Somatic mutation profile of tumor specimen 0DPFMI from CCDI case PBCDPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.5 years (3,457 days).
Specimen 0DPFMI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64dc4f17-8cdd-4451-9848-5fdbf6af0ca2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPFM8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e24a543c-ecfc-48a2-8682-cf9285502c39

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'UTR 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 195/432 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GID8 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs762677628, COSV99824210; called by muse, mutect2, varscan2
- GPR78 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV66764066; called by muse, mutect2
- KDM5A | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs747207978; called by muse, mutect2, varscan2
- TH | c.998G>T p.S333I (on ENST00000381178 / NM_199292.3; = p.S302I on NM_000360.4) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60768396; called by muse, mutect2
- ZNF600 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs754308959, COSV57745336; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 21/560 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- SPAG1 | c.833-1G>A p.X278_splice | Splice Site (SNP) | VAF 94/288 reads (33%) | called by muse, mutect2, varscan2
- SPAG17 | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 21/497 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- XKR5 | c.1538A>T p.K513M | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.212); called by muse, mutect2
- FTCD | c.*95C>T | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- NGEF | c.*42C>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs774989406; called by mutect2, varscan2
- XRCC1 | c.415-77C>T | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
